Surgical pathology report (de-identified scan), TCGA case TCGA-TM-A84R, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site The University of New South Wales, specimen TCGA-TM-A84R-01A (Primary Tumor).

[page 1 of 5]
Case:
Collected:
Ordered by:

CLINICAL DETAILS

Left frontal mass. ?low grade glioma. ?metastasis. ?lymphoma.

FROZEN SECTION REPORT

SPECIMEN: "LEFT FRONTAL MASS FROZEN SECTION".

REPORT: Glioma. No definite high grade features seen but increased cellularity noted. Await paraffin sections for further grading.

PHONED TO:

Ext:

DATE:

TIME:

REPORTED BY:

SECTIONED BY:

Clinical history:

see above

Imaging findings:

MRI brain

FIRST SEIZURE PRESENTATION -

LEFT FRONTAL NON-ENHANCING CYSTIC LESION ON MRI SCAN DONE IN

(FOR INTRAOPERATIVE MRI). Initial sequences demonstrate a large intra-axial mass lesion within the left frontal lobe measuring up to 7.5 x 3.3cm in maximum axial dimension and with a partially cystic component superiorly. Following sequences demonstrate resection of a large component of the lesion without apparent complication. Please see Surgeon's report for details."

Radiological Size of Lesion:

7.5 x 3.3cm

Contrast enhancement:

non enhancing

Current and previous treatment:

nil stated

Previous pathology lab number:

nil present

Anatomical site:

frontal lobe

Intra-axial/extra-axial:

intra-axial

Laterality of tumour:

left

Specimen type:

biopsy

Clinical or differential diagnosis:

?low grade glioma. ?metastasis. ?lymphoma.

MACROSCOPIC DESCRIPTION

Two specimens received.

1. "LEFT FRONTAL MASS FROZEN SECTION". There are two reddish tan fragments measuring 5mm and 2mm. First half of largest piece bisected and embedded in block A and two smears made, H+E and tol blue. ie frozen section piece has been kept frozen and residual tissue embedded in block A.

ICD-O-3
Oligodendroglioma, grade II 9450/3
Site Brain, supratentorial NOS C71.0
path
Brain, frontal lobe C71.1
2010/20/13

[page 2 of 5]
Histopathology Report

Temporary Copy

Case: .

Collected:

Ordered by: .

2. "LEFT FRONTAL MASS HISTOPATHOLOGY". There is one fragment of pale partially very soft and haemorrhagic tissue, aggregating to 35 x 20 x 13mm. All embedded from block A-D.

MICROSCOPIC REPORT

Specimen 1 and 2 show features of Oligodendroglioma WHO (2007) Grade II.

The tumour is infiltrative and is of moderate to dense cellularity. It is composed of mostly round to oval cells displaying mild nuclear pleomorphism, perinuclear halos and set in a fibrillary background. Delicate branching vascular network is evident. In some areas, the tumour has a demarcated pushing edge and the adjacent brain is severely gliotic with many gemistocytic astrocytes and rosenthal-like fibres are seen (block 2D). There is perivascular lymphocytic cuffing. There is adjacent brain cortex and leptomeninges seen in block 2A. Perinuclear satellitosis is not a feature in this biopsy. Mitotic figures are very infrequent with only two isolated mitosis identified in all tumour blocks. There is no necrosis or endothelial proliferation.

Immunohistochemistry was performed:

IDH 1 (R132H):

GFAP:

p53:

EGFR:

Ki-67:

Microscopic findings:	see above
Histological tumour type:	Oligodendroglioma
Histological tumour grade:	WHO (2007) grade II
Brain invasion (for meningiomas):	n/a
Artefacts impacting specimen:	nil significant

ANCILLARY TEST FINDINGS

Immunohistochemical stains block: 2A

Immunohistochemical stains result:

IDH 1 (R132H): **NEGATIVE**

Positive antibodies: GFAP (patchy), EGFR (moderate), p53 (20% nuclei)

Negative antibodies: IDH1(R132H)

Equivocal antibodies:

Ki-67 labelling index: 5%

Molecular pathology testing:	FISH for 1p/19q and EGFR. IDH sequencing
------------------------------	---

Research consent: yes

Research block: 2B

[page 3 of 5]
Histopathology Report Temporary Copy

Case:

Collected:

Ordered by

SUMMARY

Specimen 1 and 2, Left frontal mass:

- Oligodendroglioma WHO (2007) grade II
- IDH1 (R132H) negative on immunohistochemistry
- Supplementary reports with molecular studies to follow

REPORTED BY

[page 4 of 5]
Histopathology Supplementary Temporary Copy

Case: 1
Collected:
Ordered by:

SUPPLEMENTARY REPORT

RPAH GLIOMA FISH RESULTS: This case was analysed for 1p/19q LOH using dual colour probe sets 1p36/1q25 and 19q13/19p13. Cut-off values: a 1p/1q ratio and 19q/19p ratio of <-0.80 is taken as indicating LOH. Sixty cells were formally scored with each probe pair.

The case was also hybridised with EGFR/Cep7 dual colour FISH probeset to assess EGFR gene amplification.

Chromosome 1
Mean copies 1p per cell: 1.32
Mean copies 1q per cell: 1.92
1p/1q ratio: 0.687
Interpretation: 1p loss detected by FISH

Chromosome 19
Mean copies 19q per cell: 1.08
Mean copies 19p per cell: 1.87
19q/19p ratio: 0.58
Interpretation: 19q loss detected by FISH

EGFR: Not amplified (mean copies EGFR/cell= 1.95).

COMMENT: Dual 1p/19q loss detected, consistent with oligodendroglial phenotype. No EGFR amplification detected.

Reported by:

This case was also referred to for IDH1 gene sequencing. They report an IDH2 (R172M) mutation (see separate report

SUPPLEMENTARY SUMMARY

- Specimen 1 and 2, Left frontal mass:
- Oligodendroglioma WHO (2007) grade II
- IDH2 (R172M) mutation detected by external laboratory
- 1p/19q codeletion detected by FISH
- No EGFR amplification

REPORTED BY:

[page 5 of 5]
Neuropathology Report

Temporary Copy

Case:
Collected:
Ordered by:

CLINICAL HISTORY

Block 2B. Oligodendroglioma with 1p/19q codeletion but negative on IHC for IDH1 (R132H). For sequencing please.

SPECIMEN DESCRIPTION

1 vial of FFPE sections for IDH sequencing

REPORT

Neuropathology Report IDH1 and IDH2 MUTATION STATUS

HISTOLOGICAL ASSESMENT:

The sample was review by a pathologist and estimated to contain at least 50 % tumour cells.

METHOD:

Codon 132 of the *IDH1* gene and codon 172 of the *IDH2* gene are amplified and sequenced by pyrosequencing.

RESULTS:

IDH1: No Mutation Detected

IDH2: MUTATION DETECTED - R172M

The HGVS nomenclature for this mutation is NM_002168.2(*IDH2*): c.515G>T (p.R172M)

COMMENTS

This result indicates that the tumour harbours the *IDH2* (p.R172M) mutation.

No *IDH1* codon 132 mutation was present.

Note: All PCR based tests are subject to a low risk of non-amplification of one allele due to primer binding site single nucleotide polymorphisms (SNP). This can lead to a false negative result.

Sample fixation causes DNA degradation which may result in false negative results due to non-amplification of one allele (allelic drop out) or false positive results due to trans-lesional nucleotide repair during PCR amplification.

SUMMARY

This result indicates that the tumour harbours the *IDH2* (p.R172M) mutation.

REPORTED BY:

Source: NCI Genomic Data Commons file 562df126-ee15-441e-b291-ac27d0baf934 (TCGA-TM-A84R.3182D6DB-4B2D-49B0-A907-5DD62812D470.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).